Gene-level copy-number profile of tumor specimen TCGA-CV-A45W-01A from TCGA case TCGA-CV-A45W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.0 years (27,743 days).
Specimen TCGA-CV-A45W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0bedd555-ca6f-4262-bc6c-69a66d67a3b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A45W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/52f2c35b-8a30-4458-aa14-1c090a69979d

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,321; copy number 3: 4,694; copy number 4: 13,245; copy number 5: 17,057; copy number 6: 11,624; copy number 7: 6,252; copy number 8: 1,715; copy number 9: 1,909; copy number 10: 929; copy number 11: 14; copy number 12: 806; copy number 13: 138; copy number 16: 50; copy number 20: 1; copy number 21: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A45W-01A-11D-A253-01): tumor purity 0.42, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,067 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–94,507,620, 14 genes, copy number 11: HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:141,051,347–190,832,173, 804 genes, copy number 12 (broad region; genes not listed).
- chr8:37,405,439–39,310,443, 66 genes, copy number 13 (broad region; genes not listed).
- chr8:46,028,804–47,960,178, 39 genes, copy number 13 (within-gene range 6–13): AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA.
- chr11:81,552,226–81,556,425, 2 genes, copy number 12: MTND4LP18, MTND6P25.
- chr12:7,812,512–8,242,948, 33 genes, copy number 13 (within-gene range 8–13): SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA, AC006511.1, AC006511.4, HSPD1P12, AC006511.2, FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A, FAM66C, DEFB109F, AC092111.2, AC092111.1, FAM90A1, ALG1L10P, FAM86FP, LINC02449.
- chr14:22,123,318–22,505,167, 58 genes, copy number 21: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36.
- chr14:103,912,288–105,315,589, 51 genes, copy number 16–20 (within-gene range 6–20): ATP5MPL, TDRD9, RD3L, RN7SL634P, ASPG, MIR203A, MIR203B, AL359399.1, KIF26A, LINC02691, AL512357.2, AL512357.1, RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, AL512356.5, JAG2, MIR6765, AL512356.1, NUDT14, BRF1, BTBD6.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
